Surgical pathology report (de-identified scan), TCGA case TCGA-YS-AA4M, project TCGA-MESO (Mesothelioma), tissue source site Barretos Cancer Hospital, specimen TCGA-YS-AA4M-01A (Primary Tumor).

ICD-3
Mesothelioma, malignant 905613
Site: Pleura NOS C38.4
920 8/8/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Pleura

“Biopsy from right pleura (samples 1 and 2)”:

Mesothelioma

Note: See exam bellow.

Immunohistochemistry exam:

The morphological findings associated with immunohistochemical panel are compatible with Mesothelioma.

Source: NCI Genomic Data Commons file d3c38588-8c4a-4059-b140-61f4906aa465 (TCGA-YS-AA4M.90EF92D1-7D02-4A39-8C93-5F88EAC28516.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).